Somatic mutation profile of tumor specimen HCM-STAN-1113-C18-01A (aliquot HCM-STAN-1113-C18-01A-11D-A937-36) from HCMI case HCM-STAN-1113-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 68.9 years (25,168 days).
Specimen HCM-STAN-1113-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63c10d2a-5e40-416b-ada4-8f07c2635855.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1113-C18-11A (Solid Tissue Normal), aliquot HCM-STAN-1113-C18-11A-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43639a4b-f361-4f50-870a-4201f27920a5

The open-access MAF lists 195 somatic variants for this specimen: 135 protein-altering or splice-affecting, 57 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 57, Nonsense Mutation 10, Frame Shift Del 4, 5'Flank 2, Splice Region 2, Frame Shift Ins 2, Splice Site 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 67/370 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 67/370 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 83/452 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.13458T>G p.I4486M | Missense Mutation (SNP) | VAF 258/367 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs768679977; called by muse, mutect2, varscan2
- AL645922.1 | c.2157del p.C720Afs*21 | Frame Shift Del (DEL) | VAF 238/527 reads (45%) | catalogued as COSV54959013; called by mutect2, varscan2
- AP4B1 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 238/373 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1427848579; called by muse, mutect2, varscan2
- APBA1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 47/736 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454451021, COSV55237715, COSV99596318; called by muse, mutect2
- APBA2 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 131/437 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1441180683, COSV68794088; called by muse, mutect2, varscan2
- ARMC4 | c.1046G>T p.R349M | Missense Mutation (SNP) | VAF 91/478 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV53462778; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 180/820 reads (22%) | catalogued as COSV63438584; called by muse, mutect2, varscan2
- ASB5 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 82/423 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs768506681, COSV56672361, COSV99641542; called by muse, mutect2, varscan2
- ASMTL | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 341/907 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs745929353; called by muse, mutect2, varscan2
- ATCAY | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 363/615 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs753265304, COSV56659243; called by muse, mutect2, varscan2
- BRD4 | c.3576G>A p.K1192= | Splice Region (SNP) | VAF 169/440 reads (38%) | catalogued as COSV99650096; called by muse, mutect2, varscan2
- BRWD3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs1057521931, COSV64745244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTG2 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 165/874 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104392379; called by muse, mutect2, varscan2
- CARS2 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 137/791 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV57284777; called by muse, mutect2, varscan2
- CDH23 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 105/603 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1064796283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDS2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 66/601 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66896521; called by muse, mutect2, varscan2
- CFAP65 | c.2744G>T p.W915L | Missense Mutation (SNP) | VAF 247/699 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100445409; called by muse, mutect2, varscan2
- CNMD | c.75G>A p.A25= | Splice Region (SNP) | VAF 88/355 reads (25%) | catalogued as rs1242035496; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 68/464 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, varscan2
- COL23A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 148/607 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs780431788, COSV101177977; called by muse, mutect2, varscan2
- CSMD1 | c.9886G>A p.G3296S (on ENST00000520002; = p.G3295S on NM_033225.6) | Missense Mutation (SNP) | VAF 109/640 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757638862, COSV100145033; called by muse, mutect2, varscan2
- CTNND2 | c.3269A>G p.Y1090C | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1214249938; called by muse, mutect2, varscan2
- CUL7 | c.352A>C p.I118L | Missense Mutation (SNP) | VAF 163/649 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs1314580995; called by muse, mutect2, varscan2
- DIAPH2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 199/561 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779897805; called by muse, mutect2, varscan2
- DLGAP3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 133/385 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs766267134, COSV52392724; called by muse, mutect2, varscan2
- DOP1A | c.6455G>A p.R2152H | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1187215002; called by muse, mutect2, varscan2
- FBLN1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 144/569 reads (25%) | catalogued as rs1169120464; called by muse, mutect2, varscan2
- FRMPD1 | c.3661G>A p.V1221I | Missense Mutation (SNP) | VAF 147/490 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs200892375; called by muse, mutect2, varscan2
- FRMPD3 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 251/707 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as rs747111514, COSV52190816; called by muse, mutect2, varscan2
- FSIP2 | c.6247C>T p.R2083* | Nonsense Mutation (SNP) | VAF 50/506 reads (10%) | catalogued as rs758314634, COSV58079688; called by muse, mutect2, varscan2
- GALNT9 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 149/598 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100202059; called by muse, mutect2, varscan2
- GMPS | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV55812251; called by muse, mutect2, varscan2
- GOLM1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 52/858 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs1404573530, COSV99974368; called by muse, mutect2
- ICAM5 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 147/737 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV55748695; called by muse, mutect2, varscan2
- IGHG4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 178/1750 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs763568423; called by muse, mutect2, varscan2
- ITPR1 | c.4612C>T p.R1538W (on ENST00000354582; = p.R1523W on NM_002222.7) | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs765591834, COSV56975681; called by muse, mutect2, varscan2
- KIF20B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99590593; called by muse, mutect2, varscan2
- MAGEC2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 331/923 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV56001479; called by muse, mutect2, varscan2
- MAML3 | c.2938G>C p.G980R | Missense Mutation (SNP) | VAF 265/623 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV72208473; called by muse, mutect2, varscan2
- MMP28 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 161/895 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs370540313; called by muse, mutect2, varscan2
- MSGN1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 34/844 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV55263497; called by muse, mutect2
- NR3C1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 308/441 reads (70%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as rs1460349075; called by muse, varscan2
- NUBP2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 109/631 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as rs749827351; called by muse, mutect2, varscan2
- OR51V1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 106/511 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs774588813, COSV58315645; called by muse, varscan2
- OTOA | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 115/638 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs777719065; called by muse, mutect2, varscan2
- OTOGL | c.5015G>C p.R1672P (on ENST00000547103; = p.R1663P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100086838, COSV100087488; called by muse, mutect2, varscan2
- PCDH17 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 81/498 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.787); catalogued as COSV100931455; called by muse, mutect2, varscan2
- PCDHA10 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 107/805 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56490353; called by muse, mutect2, varscan2
- PCDHB5 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 180/942 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1307227233, COSV50647275; called by muse, varscan2
- PDGFB | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58648431; called by muse, mutect2, varscan2
- PIK3CG | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 339/841 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63248254; called by muse, mutect2, varscan2
- PMS1 | c.2342G>A p.S781N | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV59715190; called by muse, mutect2
- PRDM8 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 109/460 reads (24%) | catalogued as COSV60203539; called by muse, mutect2, varscan2
- PRR32 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 182/984 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs1412006452; called by muse, mutect2, varscan2
- PRR32 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 172/959 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs887535258, COSV64420781; called by muse, varscan2
- PRRG1 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 137/656 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV101068995, COSV66157819; called by muse, mutect2, varscan2
- PTPRN | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as COSV55350443; called by muse, mutect2, varscan2
- RNF150 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 117/548 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60800961; called by muse, mutect2, varscan2
- RSBN1 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs748962265; called by muse, mutect2, varscan2
- RUNX1 | c.420_425dup p.S140_G141dup (on ENST00000344691 / NM_001001890.3; = p.S167_G168dup on NM_001754.5) | In Frame Ins (INS) | VAF 42/228 reads (18%) | catalogued as COSV55877062, COSV55879923; called by mutect2, varscan2
- RYR2 | c.3089C>T p.P1030L | Missense Mutation (SNP) | VAF 67/508 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1404965456; ClinVar: uncertain significance; called by muse, varscan2
- S100A10 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 129/654 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV64290942; called by muse, mutect2, varscan2
- SH3BGRL | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 148/797 reads (19%) | catalogued as COSV100943503, COSV64621017, COSV64621276; called by muse, mutect2, varscan2
- SLC26A11 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 247/653 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs141463339; called by muse, mutect2, varscan2
- SLC5A2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 118/611 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs564929531; called by muse, mutect2, varscan2
- SLC5A5 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 137/706 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55831934; called by muse, varscan2
- SLCO1A2 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753971254; called by muse, mutect2, varscan2
- SMC2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs1319540048; called by muse, mutect2
- SPDYE4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 146/461 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as rs569077736; called by muse, mutect2, varscan2
- STRN | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs200449462, COSV55752953; called by muse, mutect2, varscan2
- SVEP1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 96/646 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs548514380, COSV57027534; called by muse, mutect2, varscan2
- TACR1 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 257/678 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537616; called by muse, mutect2, varscan2
- TENM1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 160/839 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778994121, COSV64432201, COSV64439008; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 194/500 reads (39%) | catalogued as rs777727562, COSV69855816; called by muse, varscan2
- TMEM11 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 181/902 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV58313231; called by muse, mutect2, varscan2
- TNXB | c.9553G>A p.A3185T (on ENST00000647633; = p.A2938T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/461 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs780721675, COSV64488384; called by muse, mutect2, varscan2
- URB2 | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 236/659 reads (36%) | catalogued as rs540815059; called by muse, mutect2, varscan2
- WDR91 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 114/759 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs745637947, COSV60368508; called by muse, mutect2, varscan2
- YTHDF1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 159/1224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757745929; called by muse, mutect2, varscan2
- ZNF330 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764846328; called by muse, mutect2, varscan2
- ZNF543 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 310/748 reads (41%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.971); catalogued as rs771063500, COSV58629268; called by muse, mutect2, varscan2
- ZNF865 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 180/890 reads (20%) | SIFT deleterious (0.03); catalogued as rs781501689; called by muse, mutect2, varscan2
- ACOX2 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 132/617 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPAT3 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 122/415 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AGRN | c.5564-1G>A p.X1855_splice | Splice Site (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- ANK3 | c.9304G>T p.G3102W | Missense Mutation (SNP) | VAF 29/631 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AVIL | c.2003A>G p.K668R | Missense Mutation (SNP) | VAF 127/504 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BAIAP3 | c.1571del p.P524Lfs*15 | Frame Shift Del (DEL) | VAF 76/422 reads (18%) | called by mutect2, varscan2
- C1orf35 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 96/710 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC169 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CNTN1 | c.1847G>C p.R616T | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.03); called by muse, mutect2
- COPE | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 195/855 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DMRTC2 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 81/517 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ELOVL2 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 104/459 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAM200B | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- FOLR1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 115/529 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GPC3 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 278/742 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- GPR20 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 402/1164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC2 | c.2207A>C p.N736T | Missense Mutation (SNP) | VAF 176/748 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IRF2BP2 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 294/791 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- IRF2BPL | c.1052_1062del p.A351Gfs*68 | Frame Shift Del (DEL) | VAF 248/559 reads (44%) | called by mutect2, varscan2
- ITGB5 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- JAKMIP3 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 71/410 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 357/507 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDRBS3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- LRRC31 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LRRK1 | c.4081A>G p.M1361V | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MAML3 | c.2939G>C p.G980A | Missense Mutation (SNP) | VAF 266/624 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAN1A2 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAP3K14 | c.2419G>C p.D807H | Missense Mutation (SNP) | VAF 183/480 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MDH1B | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 194/516 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MFAP3L | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 99/579 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MFSD8 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MIPOL1 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 101/443 reads (23%) | called by muse, mutect2, varscan2
- NBPF14 | c.8516C>T p.P2839L | Missense Mutation (SNP) | VAF 72/775 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCBP1 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 44/452 reads (10%) | called by muse, mutect2
- PCDHGA8 | c.1629C>G p.S543R | Missense Mutation (SNP) | VAF 40/978 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- PEAK1 | c.3677G>C p.R1226T | Missense Mutation (SNP) | VAF 31/732 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PHF2 | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 77/524 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PHF2 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 79/529 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PTPRT | c.799T>G p.C267G | Missense Mutation (SNP) | VAF 485/888 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGMB | c.362G>A p.C121Y (on ENST00000513185 / NM_001366508.1; = p.C162Y on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 509/691 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5B | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 297/621 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); called by muse, varscan2
- SLC7A13 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 111/530 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNW1 | c.1149T>G p.N383K | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STRN | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 300/776 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYN2 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 132/481 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TAAR8 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 217/436 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TGIF1 | c.308_309dup p.E104Wfs*4 (on ENST00000330513 / NM_001374396.1; = p.E124Wfs*4 on NM_003244.4) | Frame Shift Ins (INS) | VAF 228/384 reads (59%) | called by mutect2, varscan2
- UNC13C | c.1689T>G p.D563E | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF534 | c.547dup p.S183Ffs*13 (on ENST00000332323 / NM_001143939.3; = p.S170Ffs*13 on NM_001143938.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 62/436 reads (14%) | called by mutect2, varscan2
- ZNF687 | c.175del p.A59Lfs*23 | Frame Shift Del (DEL) | VAF 304/758 reads (40%) | called by mutect2, varscan2
- ACE | c.996C>T p.S332= | Silent (SNP) | VAF 264/719 reads (37%) | catalogued as rs767127845, COSV52006685; called by muse, mutect2, varscan2
- ADAM12 | c.2421G>A p.L807= | Silent (SNP) | VAF 134/598 reads (22%) | catalogued as COSV64134379; called by muse, mutect2, varscan2
- ADCY5 | c.2616C>T p.S872= | Silent (SNP) | VAF 149/621 reads (24%) | catalogued as rs766902305, COSV100567124; called by muse, mutect2, varscan2
- ADH1B | c.810C>T p.I270= | Silent (SNP) | VAF 74/521 reads (14%) | catalogued as rs904388509; called by muse, varscan2
- ANK1 | c.4579C>T p.L1527= | Silent (SNP) | VAF 109/604 reads (18%) | called by muse, mutect2, varscan2
- BASP1 | c.513C>T p.D171= | Silent (SNP) | VAF 123/572 reads (22%) | called by muse, mutect2, varscan2
- CBLB | c.2574C>G p.P858= | Silent (SNP) | VAF 74/319 reads (23%) | called by muse, mutect2, varscan2
- CELF6 | c.1041C>T p.P347= | Silent (SNP) | VAF 76/568 reads (13%) | catalogued as rs1047976329; called by muse, mutect2, varscan2
- CLIP3 | c.393C>T p.H131= | Silent (SNP) | VAF 121/349 reads (35%) | catalogued as rs767475996; called by muse, mutect2, varscan2
- COL4A1 | c.3645G>A p.P1215= | Silent (SNP) | VAF 179/771 reads (23%) | catalogued as rs765336200, COSV65422256; called by muse, mutect2, varscan2
- CTNND2 | c.777G>T p.L259= | Silent (SNP) | VAF 47/281 reads (17%) | called by muse, varscan2
- EGF | c.252T>C p.N84= | Silent (SNP) | VAF 119/481 reads (25%) | catalogued as rs750616729; called by muse, mutect2, varscan2
- EPHA3 | c.1782G>A p.R594= | Silent (SNP) | VAF 74/298 reads (25%) | called by muse, mutect2, varscan2
- EPHB6 | c.1974C>T p.A658= | Silent (SNP) | VAF 124/684 reads (18%) | called by muse, varscan2
- GLI2 | c.2661G>A p.P887= (on ENST00000361492 / NM_001374353.1; = p.P904= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 206/939 reads (22%) | catalogued as rs1053909489; called by muse, mutect2, varscan2
- GRIP2 | c.312G>T p.R104= (on ENST00000619221; = p.R7= on NM_001080423.4) | Silent (SNP) | VAF 102/487 reads (21%) | called by muse, mutect2, varscan2
- INPP5D | c.3288G>A p.A1096= (on ENST00000445964 / NM_001017915.3; = p.A1095= on NM_005541.5) | Silent (SNP) | VAF 40/1124 reads (4%) | catalogued as rs1328756989; called by muse, mutect2
- KCNH3 | c.2766G>A p.S922= | Silent (SNP) | VAF 166/661 reads (25%) | catalogued as rs140591831; called by muse, mutect2, varscan2
- KSR2 | c.864G>A p.P288= | Silent (SNP) | VAF 109/731 reads (15%) | catalogued as rs771169274, COSV60393836; called by muse, mutect2, varscan2
- LRRC8E | c.1875C>T p.S625= | Silent (SNP) | VAF 291/723 reads (40%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2457C>A p.S819= | Silent (SNP) | VAF 30/1036 reads (3%) | called by muse, mutect2
- MAP3K10 | c.936G>A p.A312= | Silent (SNP) | VAF 109/615 reads (18%) | catalogued as rs748129608; called by muse, varscan2
- MAP3K7CL | c.723G>A p.S241= | Silent (SNP) | VAF 52/304 reads (17%) | catalogued as rs767209465; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1182C>T p.I394= | Silent (SNP) | VAF 64/402 reads (16%) | catalogued as rs769496083; called by muse, mutect2, varscan2
- MN1 | c.3720C>T p.D1240= | Silent (SNP) | VAF 161/551 reads (29%) | catalogued as COSV56558967; called by muse, mutect2, varscan2
- MUC16 | c.10425C>A p.T3475= | Silent (SNP) | VAF 126/675 reads (19%) | catalogued as COSV101199136; called by muse, mutect2, varscan2
- MUC5B | c.14118C>T p.T4706= | Silent (SNP) | VAF 162/798 reads (20%) | called by muse, mutect2, varscan2
- MUC6 | c.6531G>C p.S2177= | Silent (SNP) | VAF 248/978 reads (25%) | catalogued as COSV101424385, COSV70145016; called by muse, mutect2, varscan2
- NDST3 | c.1983C>T p.T661= | Silent (SNP) | VAF 42/450 reads (9%) | catalogued as rs1446469120; called by muse, mutect2
- OTOG | c.8349C>T p.I2783= | Silent (SNP) | VAF 38/536 reads (7%) | catalogued as rs1449287595; called by muse, mutect2
- PCDHA7 | c.2307C>T p.L769= | Silent (SNP) | VAF 112/507 reads (22%) | called by muse, mutect2, varscan2
- PCDHB3 | c.1617G>A p.P539= | Silent (SNP) | VAF 253/1373 reads (18%) | catalogued as rs1251485802; called by muse, mutect2, varscan2
- POLR2H | c.342G>A p.A114= | Silent (SNP) | VAF 118/589 reads (20%) | catalogued as rs202151346, COSV52615447; called by muse, mutect2, varscan2
- PSMB7 | c.777C>A p.I259= | Silent (SNP) | VAF 80/566 reads (14%) | called by muse, mutect2, varscan2
- PTPN9 | c.1170A>G p.V390= | Silent (SNP) | VAF 205/474 reads (43%) | catalogued as rs763844646; called by muse, mutect2, varscan2
- PTPRS | c.315C>T p.Y105= | Silent (SNP) | VAF 125/658 reads (19%) | catalogued as rs1232998256; called by muse, mutect2, varscan2
- RASAL1 | c.375G>A p.Q125= | Silent (SNP) | VAF 110/491 reads (22%) | catalogued as COSV55658357; called by muse, mutect2, varscan2
- RBMXL3 | c.609C>T p.P203= | Silent (SNP) | VAF 213/995 reads (21%) | called by muse, mutect2, varscan2
- RTP2 | c.240C>T p.R80= | Silent (SNP) | VAF 97/619 reads (16%) | catalogued as rs1428483091, COSV64078743, COSV64079249; called by muse, mutect2, varscan2
- SCN3A | c.4245A>C p.T1415= | Silent (SNP) | VAF 58/408 reads (14%) | called by muse, mutect2, varscan2
- SLC17A6 | c.1296T>G p.V432= | Silent (SNP) | VAF 51/312 reads (16%) | called by muse, mutect2, varscan2
- SLC38A9 | c.1372T>C p.L458= | Silent (SNP) | VAF 135/528 reads (26%) | called by muse, mutect2, varscan2
- STPG2 | c.703C>T p.L235= | Silent (SNP) | VAF 100/456 reads (22%) | catalogued as rs1414849290; called by muse, mutect2, varscan2
- STRIP2 | c.1059C>T p.D353= | Silent (SNP) | VAF 84/410 reads (20%) | catalogued as rs1046028694; called by muse, mutect2, varscan2
- TAF11 | c.345G>A p.E115= | Silent (SNP) | VAF 25/359 reads (7%) | called by muse, mutect2
- THBS2 | c.2364C>A p.I788= | Silent (SNP) | VAF 113/575 reads (20%) | called by muse, mutect2, varscan2
- TMCO4 | c.342G>A p.T114= | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as rs201632654; called by muse, mutect2, varscan2
- TMEM69 | c.186G>A p.Q62= | Silent (SNP) | VAF 118/353 reads (33%) | catalogued as COSV63432342; called by muse, mutect2, varscan2
- TPO | c.1416C>A p.G472= | Silent (SNP) | VAF 201/932 reads (22%) | catalogued as COSV100221770; called by muse, mutect2, varscan2
- TRBJ2-5 | c.33G>A p.T11= | Silent (SNP) | VAF 140/830 reads (17%) | called by muse, mutect2, varscan2
- TREX1 | c.111G>A p.L37= (on ENST00000625293 / NM_033629.6; = p.L27= on NM_007248.5) | Silent (SNP) | VAF 148/704 reads (21%) | catalogued as rs1203330883; called by muse, mutect2, varscan2
- TRHDE | c.261C>T p.G87= | Silent (SNP) | VAF 177/719 reads (25%) | catalogued as rs768763758; called by muse, mutect2, varscan2
- TRIM42 | c.528C>T p.H176= | Silent (SNP) | VAF 140/596 reads (23%) | catalogued as COSV53883295; called by muse, mutect2, varscan2
- TTYH1 | c.498G>A p.T166= | Silent (SNP) | VAF 194/1036 reads (19%) | catalogued as rs762808281, COSV100002018; called by muse, mutect2, varscan2
- VHLL | c.99G>A p.E33= | Silent (SNP) | VAF 128/643 reads (20%) | catalogued as COSV100372635; called by muse, mutect2, varscan2
- WT1 | c.279C>T p.G93= | Silent (SNP) | VAF 204/700 reads (29%) | called by muse, mutect2, varscan2
- XKR5 | c.273G>A p.Q91= | Silent (SNP) | VAF 137/755 reads (18%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892647 G>A | 5'Flank (SNP) | VAF 121/548 reads (22%) | catalogued as rs1435662940; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415143 G>C | 5'Flank (SNP) | VAF 147/751 reads (20%) | called by muse, mutect2, varscan2
- NPAP1L | n.391A>C | RNA (SNP) | VAF 32/174 reads (18%) | catalogued as rs3884159; called by muse, mutect2
